Somatic mutation profile of tumor specimen MMRF_1771_1_BM_CD138pos (aliquot MMRF_1771_1_BM_CD138pos_T1_KBS5U_K11343) from MMRF case MMRF_1771, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,355 days).
Specimen MMRF_1771_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed4e234e-021f-4569-83ff-76beeb1663e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1771_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1771_1_PB_CD3pos_C2_KBS5U_K11344; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/798d3c9d-8522-490c-b9bd-57b6782a9bf2

The open-access MAF lists 113 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 28, Intron 20, Silent 12, Frame Shift Del 4, 5'UTR 3, RNA 2, 5'Flank 2, In Frame Del 2, 3'Flank 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 50/52 reads (96%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTR3B | c.769A>T p.T257S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1191858203; called by muse, mutect2, varscan2
- CROCC2 | c.4111C>T p.R1371W | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1007519887; called by muse, mutect2, varscan2
- CSDC2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373284212, COSV99348055; called by muse, mutect2, varscan2
- DDIT4 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs139203737; called by muse, mutect2, varscan2
- DHRSX | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749531724; called by muse, mutect2, varscan2
- DNAAF5 | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1258388026; called by muse, mutect2, varscan2
- FHOD3 | c.1720G>T p.G574W (on ENST00000359247 / NM_001281739.3; = p.G591W on NM_025135.5) | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as rs1339334317, COSV57190421; called by muse, mutect2, varscan2
- GUCY2D | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs769749617; called by muse, mutect2, varscan2
- HTR3B | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV52745133; called by muse, mutect2
- IGHD2-2 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 15/15 reads (100%) | catalogued as rs782426021; called by muse, varscan2
- IGHV2-70 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs534782395; called by muse, mutect2, varscan2
- IGHV2-70D | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as rs1379376791; called by muse, varscan2
- KCNA7 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99671962; called by muse, mutect2, varscan2
- MYBPC1 | c.301G>A p.D101N (on ENST00000550270 / NM_206820.2; = p.D126N on NM_002465.4) | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62251052; called by muse, mutect2
- OR14I1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV61200584; called by muse, mutect2, varscan2
- PEAK1 | c.3149A>G p.H1050R | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs763720694; called by muse, mutect2, varscan2
- RNF157 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs747917834; called by muse, mutect2, varscan2
- TECTA | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV50690167; called by muse, mutect2
- TK2 | c.464C>T p.A155V (on ENST00000299697; = p.A211V on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1321672304; called by muse, mutect2, varscan2
- TMEM182 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV68424239, COSV99072090; called by muse, mutect2
- TRIM75P | c.61del p.D21Ifs*3 | Frame Shift Del (DEL) | VAF 71/179 reads (40%) | catalogued as COSV72295884; called by mutect2, pindel, varscan2
- ZKSCAN5 | c.1422_1424del p.K475del | In Frame Del (DEL) | VAF 47/150 reads (31%) | catalogued as rs1183748912; called by pindel, varscan2
- ABCB1 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASTN2 | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CCNG2 | c.594T>G p.F198L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCSER1 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FHOD3 | c.1955C>A p.T652N (on ENST00000359247 / NM_001281739.3; = p.T669N on NM_025135.5) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.123); called by mutect2, varscan2
- GRIK2 | c.442_447del p.S148_L149del | In Frame Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- LRP1B | c.9224T>G p.L3075* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- MCC | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MYH10 | c.2176_2179del p.Q726Dfs*5 | Frame Shift Del (DEL) | VAF 36/62 reads (58%) | called by pindel, varscan2
- NRBP2 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUDT3 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR8G5 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- PIGG | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.778); called by muse, varscan2
- PPP6R1 | c.2507_2511del p.Q836Pfs*107 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- PPP6R1 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RIC8A | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RXFP2 | c.1784T>A p.L595Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC1A6 | c.1170-2A>C p.X390_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- SLC44A1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.985); called by muse, mutect2
- SP140 | c.1642del p.R548Gfs*45 | Frame Shift Del (DEL) | VAF 126/229 reads (55%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.6466G>C p.V2156L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- ANPEP | c.1725C>T p.T575= | Silent (SNP) | VAF 44/133 reads (33%) | called by muse, mutect2, varscan2
- ATP12A | c.2349C>T p.I783= | Silent (SNP) | VAF 74/143 reads (52%) | called by muse, mutect2, varscan2
- BSPH1 | c.210G>A p.S70= | Silent (SNP) | VAF 55/184 reads (30%) | catalogued as rs150415301; called by muse, mutect2, varscan2
- CASP14 | c.267C>T p.H89= | Silent (SNP) | VAF 65/94 reads (69%) | catalogued as rs1408672307, COSV55665040, COSV99693121; called by muse, mutect2, varscan2
- HIVEP1 | c.6162T>C p.N2054= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- IFT88 | c.1350G>A p.L450= (on ENST00000319980 / NM_001318493.2; = p.L441= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.279C>T p.I93= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as rs61749003; called by muse, varscan2
- KBTBD13 | c.717C>T p.H239= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs887462336; called by muse, mutect2, varscan2
- PTS | c.222T>C p.A74= | Silent (SNP) | VAF 126/285 reads (44%) | catalogued as rs201388369; called by muse, mutect2, varscan2
- TECRL | c.492G>A p.R164= | Silent (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- THEM4 | c.51G>A p.L17= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1389583546; called by muse, mutect2
- TMEM128 | c.273C>T p.V91= (on ENST00000382753 / NM_001297552.2; = p.V67= on NM_032927.3) | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as rs1164879087; called by muse, varscan2
- AC108734.4 | n.546del | RNA (DEL) | VAF 92/452 reads (20%) | called by mutect2, pindel, varscan2
- ADCY5 | c.2930+323C>T | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- ANKMY1 | c.1565+702T>C | Intron (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- ATXN7 | c.*2308T>C | 3'UTR (SNP) | VAF 61/111 reads (55%) | called by muse, mutect2, varscan2
- BMP1 | chr8:22165218 A>T | 5'Flank (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- CALN1 | c.*3104T>C | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CALN1 | c.*1074T>A | 3'UTR (SNP) | VAF 43/124 reads (35%) | catalogued as COSV61140853; called by muse, mutect2, varscan2
- CBFA2T2 | c.*2242A>C | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- CCDC93 | c.*176G>T | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- CDON | c.*871C>T | 3'UTR (SNP) | VAF 44/85 reads (52%) | catalogued as rs148777681; ClinVar: benign; called by muse, mutect2, varscan2
- CDS1 | c.*1857T>C | 3'UTR (SNP) | VAF 78/162 reads (48%) | called by muse, mutect2, varscan2
- CDS2 | c.*6342C>T | 3'UTR (SNP) | VAF 77/78 reads (99%) | catalogued as rs1047884997; called by muse, mutect2, varscan2
- CEBPZOS | c.161-110_161-109del | Intron (DEL) | VAF 47/78 reads (60%) | catalogued as rs1198544766; called by mutect2, pindel, varscan2
- CFAP410 | c.77+707_77+713del | Intron (DEL) | VAF 18/74 reads (24%) | called by mutect2, varscan2
- COX7C | c.75+78G>A | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- DST | c.4296+4662T>G | Intron (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- ERBB4 | c.*3161T>G | 3'UTR (SNP) | VAF 101/170 reads (59%) | called by muse, mutect2, varscan2
- EVX1 | c.*358C>T | 3'UTR (SNP) | VAF 37/146 reads (25%) | catalogued as rs1261028414; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446823 T>G | 3'Flank (SNP) | VAF 74/226 reads (33%) | called by muse, mutect2, varscan2
- FAM151A | c.-33C>G | 5'UTR (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
- FAM98B | chr15:38487363 G>A | 3'Flank (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- FMN2 | c.*356A>T | 3'UTR (SNP) | VAF 35/194 reads (18%) | called by muse, mutect2, varscan2
- GAS2L2 | c.*304A>G | 3'UTR (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- GFAP | c.907-40G>A | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- GPNMB | c.541+775C>T | Intron (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- IHH | c.*523A>G | 3'UTR (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- IL12A | c.-10A>T | 5'UTR (SNP) | VAF 85/363 reads (23%) | called by muse, mutect2, varscan2
- INPP5J | c.1899+28A>G | Intron (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- LETMD1 | c.1012+104A>C | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- LIN54 | c.*2756T>C | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- LRRC38 | c.*377C>A | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- LY6G5C | c.345+1661G>C | Intron (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- MAN1B1 | c.1254+1060G>A | Intron (SNP) | VAF 82/231 reads (35%) | catalogued as rs1405445946; called by muse, mutect2, varscan2
- NEXMIF | c.*4337A>C | 3'UTR (SNP) | VAF 43/43 reads (100%) | called by muse, mutect2, varscan2
- PDPN | c.*858G>C | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- PGAP1 | c.*691T>G | 3'UTR (SNP) | VAF 71/125 reads (57%) | called by muse, mutect2, varscan2
- PPM1A | c.*1773A>C | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- QRICH1 | c.1895+146T>C | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- RAB10 | c.*28C>A | 3'UTR (SNP) | VAF 31/271 reads (11%) | called by muse, mutect2, varscan2
- RAB30 | c.361+343T>C | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- RAD18 | c.*1865C>A | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- RAP1GAP2 | c.*904C>T | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- RNGTT | chr6:88965868 C>T | 5'Flank (SNP) | VAF 37/68 reads (54%) | catalogued as rs1460082843; called by muse, mutect2, varscan2
- RPL14P1 | n.206G>A | RNA (SNP) | VAF 37/67 reads (55%) | catalogued as rs766306776; called by muse, varscan2
- SCGB2A1 | c.*161C>A | 3'UTR (SNP) | VAF 72/146 reads (49%) | called by muse, mutect2, varscan2
- SLC1A1 | c.*1503A>G | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SOWAHA | c.*1110C>G | 3'UTR (SNP) | VAF 6/155 reads (4%) | called by muse, mutect2
- SPAG17 | c.-17C>T | 5'UTR (SNP) | VAF 67/75 reads (89%) | catalogued as rs375625561; called by muse, mutect2, varscan2
- SULT1A1 | c.-5+496C>A | Intron (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2
- TNFRSF13B | c.446-758T>G | Intron (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.552-63G>A | Intron (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- TNFSF11 | c.*1058A>T | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- UGT1A7 | c.855+9159T>C | Intron (SNP) | VAF 56/71 reads (79%) | called by muse, mutect2, varscan2
- UNC5D | c.*1313C>T | 3'UTR (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- WWC2 | c.*4655G>A | 3'UTR (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- XBP1 | c.227+234C>G | Intron (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+10208G>A | Intron (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
